HCMI case HCM-SANG-0308-C15 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/f8825237-31c7-4b78-8743-efb0bd917688

Demographics
Sex at birth: male; Days to birth: -23,923 days (65.5 years before the index date).

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C16.0; Tissue or organ of origin: Esophagus, NOS; Site of resection or biopsy: Cardia, NOS; Classification of tumor: primary; Tumor grade: G3; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Esophageal columnar dysplasia degree: High Grade Dysplasia; Esophageal columnar metaplasia present: Yes; Gastric esophageal junction involvement: Yes; Uicc clinical stage: Stage IV; Uicc pathologic m: M0; Uicc pathologic n: N2; Uicc pathologic stage: Stage IIIB; Uicc pathologic t: T3; Uicc staging system edition: 7th.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine + Cisplatin + Epirubicin; Treatment intent type: Neoadjuvant; Regimen or line of therapy: ECX; Days to treatment start: 259 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Leucovorin; Treatment intent type: Neoadjuvant; Days to treatment start: 259 days.
   Recorded as not given: neoadjuvant Radiation Therapy, NOS.

Exposures
- Tobacco smoking status: Current Smoker; Alcohol intensity: Heavy Drinker.

Family history
- Relative with cancer history: no.

Biospecimens (5 samples)
- Sample HCM-SANG-0308-C15-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-SANG-0308-C15-10A-01D-A80T-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample HCM-SANG-0308-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
- Samples HCM-SANG-0308-C15-85A-01D-A80T-32, HCM-SANG-0308-C15-85A-01R-A80W-32 (2 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid.
